Somatic mutation profile of tumor specimen TCGA-49-AARO-01A (aliquot TCGA-49-AARO-01A-12D-A410-08) from TCGA case TCGA-49-AARO, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 39.8 years (14,527 days).
Specimen TCGA-49-AARO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00c2e7e1-5cac-4ff6-84ac-68d01caf2bd3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-49-AARO-11A (Solid Tissue Normal), aliquot TCGA-49-AARO-11A-11D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e3ceae3d-740d-429c-9627-6d6a6ec77947

The open-access MAF lists 635 somatic variants for this specimen: 484 protein-altering or splice-affecting, 134 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 419, Silent 134, Nonsense Mutation 34, Splice Site 20, Frame Shift Del 7, Intron 7, RNA 5, 3'Flank 2, Splice Region 2, 5'UTR 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIF1C | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs587777198, CM140690, COSV57905940; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 20/52 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA12 | c.6146C>A p.S2049* (on ENST00000272895 / NM_173076.3; = p.S1731* on NM_015657.3) | Nonsense Mutation (SNP) | VAF 8/56 reads (14%) | catalogued as COSV99788200; called by muse, mutect2, varscan2
- ABCA13 | c.4996G>T p.V1666F | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as COSV101329917; called by muse, mutect2
- ABCA9 | c.2292G>T p.R764S | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1398950693, COSV100382594; called by muse, mutect2, varscan2
- ABL1 | c.1289G>T p.W430L | Missense Mutation (SNP) | VAF 15/166 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100583417; called by muse, mutect2
- ADAD1 | c.1330C>A p.P444T | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99635061; called by muse, mutect2, varscan2
- ADAMTS20 | c.4619G>A p.R1540K | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.3); catalogued as rs1177979673, COSV101238871; called by muse, mutect2, varscan2
- ADGRL3 | c.2594C>G p.A865G (on ENST00000506720 / NM_001322402.2; = p.A797G on NM_015236.6) | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.146); catalogued as COSV101546841; called by muse, mutect2, varscan2
- ADGRL4 | c.2003C>G p.S668C | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV100875565, COSV66061653, COSV66064361; called by muse, mutect2
- AFF2 | c.3838C>A p.L1280M | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.959); catalogued as COSV99661816; called by muse, mutect2, varscan2
- AFF2 | c.3839T>A p.L1280Q | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53985204, COSV99661819; called by muse, mutect2, varscan2
- AHNAK2 | c.13456G>T p.V4486L | Missense Mutation (SNP) | VAF 21/202 reads (10%) | SIFT tolerated (0.73); PolyPhen benign (0.171); catalogued as COSV100315493; called by muse, mutect2, varscan2
- AHNAK2 | c.10804C>A p.P3602T | Missense Mutation (SNP) | VAF 66/202 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as COSV100315496; called by muse, mutect2, varscan2
- AHNAK2 | c.10372G>A p.D3458N | Missense Mutation (SNP) | VAF 28/320 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs747509619, COSV100315498; called by muse, mutect2
- AKAP12 | c.386C>A p.A129E | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV99482350, COSV99482791; called by muse, varscan2
- AKAP6 | c.698G>T p.S233I | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.592); catalogued as COSV99798166; called by muse, mutect2
- ALG10 | c.171G>T p.Q57H | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as rs1211309002, COSV56793504; called by muse, mutect2, varscan2
- ALG10 | c.171+1G>T p.X57_splice | Splice Site (SNP) | VAF 39/105 reads (37%) | catalogued as COSV99847909; called by muse, mutect2, varscan2
- ALOX12B | c.1787C>A p.P596Q | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100046628; called by muse, mutect2, varscan2
- ALOX5 | c.1607T>C p.L536P | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100979946; called by muse, mutect2, varscan2
- AMBRA1 | c.2858G>T p.G953V (on ENST00000458649 / NM_001367468.1; = p.G863V on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1273339958, COSV100092689; called by muse, mutect2, varscan2
- ANKFN1 | c.1950-1G>T p.X650_splice | Splice Site (SNP) | VAF 5/59 reads (8%) | catalogued as COSV100593094; called by muse, mutect2
- ANKS1B | c.1741G>C p.G581R | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs748402645, COSV100242758; called by muse, mutect2, varscan2
- ANO5 | c.1178G>A p.W393* | Nonsense Mutation (SNP) | VAF 5/18 reads (28%) | catalogued as rs1176480523, COSV61083055; called by muse, mutect2, varscan2
- API5 | c.970G>T p.E324* | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | catalogued as COSV101124503; called by muse, mutect2
- APLP2 | c.1893G>T p.Q631H | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.547); catalogued as COSV99599421; called by muse, mutect2, varscan2
- APOB | c.8822C>A p.T2941K | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV51936981, COSV99263491; called by muse, mutect2, varscan2
- APOB | c.1561C>A p.L521M | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.139); catalogued as COSV99263493; called by muse, mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | catalogued as COSV61389445; called by pindel, varscan2
- ARMCX2 | c.202G>T p.G68* | Nonsense Mutation (SNP) | VAF 9/43 reads (21%) | catalogued as COSV100168018; called by muse, mutect2, varscan2
- ARMCX5 | c.1407G>T p.L469F | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99863298; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.932C>A p.A311D | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.298); catalogued as COSV100771806; called by muse, mutect2, varscan2
- ARMCX6 | c.451C>A p.Q151K | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as COSV100726213; called by muse, varscan2
- ARPP21 | c.2074C>A p.L692I | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.265); catalogued as COSV99490887; called by muse, mutect2, varscan2
- ASH1L | c.1528G>T p.E510* | Nonsense Mutation (SNP) | VAF 14/69 reads (20%) | catalogued as COSV100853095; called by muse, mutect2, varscan2
- ASPH | c.301G>T p.D101Y | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV100727369, COSV62859787; called by muse, mutect2, varscan2
- ATF7IP | c.1519G>T p.E507* | Nonsense Mutation (SNP) | VAF 28/62 reads (45%) | catalogued as COSV99661164; called by muse, mutect2, varscan2
- ATMIN | c.1004G>T p.G335V | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV100214502; called by muse, mutect2, varscan2
- ATP12A | c.1583G>T p.R528L | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as rs1031193609, COSV54513986, COSV99516977; called by muse, mutect2
- ATP2A3 | c.2437G>T p.D813Y | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99988762, COSV99989635; called by muse, mutect2, varscan2
- ATP2B4 | c.3044G>T p.G1015V | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs201381891, COSV100397016; called by muse, mutect2
- ATP5PB | c.232G>T p.V78L | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as rs61752545, COSV100867612; called by muse, mutect2, varscan2
- ATP7A | c.244C>A p.P82T | Missense Mutation (SNP) | VAF 66/360 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.571); catalogued as COSV100430220; called by muse, varscan2
- ATRNL1 | c.3514G>T p.E1172* | Nonsense Mutation (SNP) | VAF 6/34 reads (18%) | catalogued as COSV100369303, COSV100372627, COSV99049658; called by muse, mutect2, varscan2
- ATRNL1 | c.3733T>A p.L1245M | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100369304; called by muse, mutect2, varscan2
- ATRNL1 | c.3734T>G p.L1245W | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100369305; called by muse, mutect2, varscan2
- AXDND1 | c.2731C>A p.Q911K | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.019); catalogued as COSV100858242; called by muse, mutect2, varscan2
- BCOR | c.2734G>T p.V912L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100652845; called by muse, mutect2, varscan2
- BCR | c.607C>G p.L203V | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100005942, COSV59929243; called by muse, mutect2, varscan2
- BIRC6 | c.11371A>G p.T3791A | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs774325819, COSV101427826; called by muse, mutect2, varscan2
- BMP5 | c.125G>T p.R42I | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63700843, COSV63703329; called by muse, mutect2, varscan2
- BNIP5 | c.460C>A p.P154T | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV101465110; called by muse, mutect2, varscan2
- BPIFA1 | c.210C>A p.N70K | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.782); catalogued as COSV100845623; called by muse, mutect2, varscan2
- BPIFA1 | c.211C>A p.L71I | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.31); catalogued as COSV100845624; called by muse, mutect2, varscan2
- BPTF | c.1937C>T p.S646L | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV58831737; called by muse, mutect2, varscan2
- BRIP1 | c.265G>T p.A89S | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV99369243; called by muse, mutect2, varscan2
- BTK | c.1479C>A p.F493L | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV100437282; called by muse, mutect2, varscan2
- BUB1 | c.2477C>T p.A826V | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs1418344624, COSV100240835; called by muse, mutect2, varscan2
- C1QTNF12 | c.380A>G p.E127G | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV100382531; called by muse, mutect2, varscan2
- C1orf127 | c.1960G>T p.G654W | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as rs949722870, COSV100983397, COSV65438965; called by muse, mutect2, varscan2
- CACNA1B | c.866G>T p.G289V | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99495113; called by muse, mutect2, varscan2
- CACTIN | c.1859A>T p.Q620L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.218); catalogued as COSV99698254; called by muse, mutect2, varscan2
- CALCA | c.273C>A p.C91* | Nonsense Mutation (SNP) | VAF 6/73 reads (8%) | catalogued as COSV100523907, COSV100524067; called by muse, mutect2
- CAMK2B | c.891G>T p.R297S | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); catalogued as COSV99322720; called by muse, mutect2
- CARS1 | c.31G>A p.G11S | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV99541948; called by muse, mutect2, varscan2
- CASR | c.1503T>A p.D501E (on ENST00000490131; = p.D578E on NM_000388.4) | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV99948441; called by muse, mutect2, varscan2
- CCDC181 | c.904C>A p.P302T | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100890245; called by muse, mutect2, varscan2
- CCDC50 | c.344T>G p.L115R | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV101165243; called by muse, mutect2
- CCDC74A | c.325G>T p.A109S | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.78); PolyPhen benign (0.043); catalogued as COSV99723543; called by mutect2, varscan2
- CCM2L | c.1168A>T p.S390C (on ENST00000452892 / NM_001365692.1; = p.T368= on NM_080625.4) | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV99394923; called by muse, mutect2
- CCNB3 | c.2632T>G p.S878A | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV52072471, COSV99328415; called by muse, mutect2, varscan2
- CD5L | c.758G>T p.C253F | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100940991; called by muse, mutect2, varscan2
- CD84 | c.973-1G>A p.X325_splice (on ENST00000311224 / NM_001184879.2; = p.X308_splice on NM_003874.4) | Splice Site (SNP) | VAF 9/51 reads (18%) | catalogued as rs764195681, COSV100245801, COSV100246318; called by muse, mutect2, varscan2
- CD84 | c.389G>T p.R130L | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV100245804; called by muse, mutect2
- CDADC1 | c.607G>T p.V203L | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV99212530; called by muse, mutect2, varscan2
- CDH19 | c.2039G>A p.S680N | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.878); catalogued as COSV100050814; called by muse, mutect2, varscan2
- CFAP36 | c.247T>A p.C83S | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV100170725, COSV59118994; called by muse, mutect2, varscan2
- CHRNA5 | c.988G>T p.V330L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV100213773; called by muse, mutect2, varscan2
- CIC | c.1117C>A p.L373I | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.987); catalogued as COSV99358932; called by muse, mutect2, varscan2
- CLDN22 | c.450T>G p.D150E | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100032776; called by muse, mutect2, varscan2
- CNGB3 | c.265C>A p.Q89K | Missense Mutation (SNP) | VAF 39/251 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV100181145, COSV60697847; called by muse, mutect2, varscan2
- CNTN1 | c.2180G>T p.W727L | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100750941; called by muse, mutect2, varscan2
- CNTN6 | c.2129G>T p.G710V | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1274588364, COSV100610043; called by muse, mutect2, varscan2
- CNTNAP4 | c.1405G>T p.V469L | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.162); catalogued as COSV100269290; called by mutect2, varscan2
- COL11A1 | c.3067G>T p.A1023S | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV100615026; called by muse, mutect2, varscan2
- COL15A1 | c.316G>A p.V106M | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.063); catalogued as rs201906975, COSV100897388; called by mutect2, varscan2
- COL17A1 | c.2576C>A p.P859Q | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV100793039; called by muse, mutect2, varscan2
- COL19A1 | c.2037G>T p.P679= | Splice Region (SNP) | VAF 12/57 reads (21%) | catalogued as COSV100505153, COSV59574835; called by muse, mutect2, varscan2
- COL3A1 | c.3628G>A p.G1210S | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs1409001837, COSV100482414; called by muse, mutect2, varscan2
- CORO6 | c.495G>T p.E165D | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.249); catalogued as COSV100801108; called by muse, mutect2, varscan2
- CPA3 | c.779C>G p.S260C | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99935941; called by muse, mutect2, varscan2
- CPS1 | c.2122A>T p.M708L | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV99242116; called by mutect2, varscan2
- CPXM2 | c.457G>T p.A153S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.794); catalogued as COSV99581022; called by muse, mutect2, varscan2
- CSMD2 | c.10417G>C p.A3473P | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV99585796; called by muse, mutect2, varscan2
- CSMD3 | c.3004+2T>A p.X1002_splice (on ENST00000297405 / NM_001363185.1; = p.X898_splice on NM_052900.3) | Splice Site (SNP) | VAF 6/35 reads (17%) | catalogued as COSV99824196; called by muse, mutect2, varscan2
- CTAGE1 | c.1981G>T p.V661F | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as COSV101194429; called by muse, mutect2, varscan2
- CTTNBP2 | c.1073G>T p.R358M | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV99352984; called by muse, mutect2, varscan2
- CUX2 | c.3755C>A p.S1252Y | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.259); catalogued as COSV99918577; called by muse, mutect2, varscan2
- CYP27B1 | c.761G>A p.C254Y | Missense Mutation (SNP) | VAF 93/145 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.568); catalogued as COSV99141491; called by muse, mutect2, varscan2
- DACH2 | c.377A>T p.E126V | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100912479; called by muse, mutect2, varscan2
- DCAF12L1 | c.779C>G p.P260R | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.564); catalogued as COSV100948074, COSV100948439; called by muse, mutect2, varscan2
- DCC | c.3486G>A p.M1162I | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV71433464; called by muse, mutect2, varscan2
- DCHS1 | c.5612G>T p.G1871V | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100201448; called by muse, mutect2
- DDN | c.1378G>C p.V460L | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV100304863; called by muse, mutect2, varscan2
- DDX4 | c.919G>T p.G307C | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100737293; called by muse, mutect2, varscan2
- DDX53 | c.1249C>A p.L417I | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV100028658; called by muse, mutect2, varscan2
- DENND2C | c.1018A>T p.K340* | Nonsense Mutation (SNP) | VAF 6/59 reads (10%) | catalogued as COSV101283886; called by muse, mutect2, varscan2
- DLEC1 | c.1345G>T p.D449Y | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100341425; called by muse, mutect2, varscan2
- DLGAP3 | c.2686C>A p.L896I | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.688); catalogued as COSV99332148; called by muse, mutect2, varscan2
- DMD | c.3546G>C p.E1182D | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.428); catalogued as COSV100817856; called by muse, mutect2, varscan2
- DNAH8 | c.13261A>T p.T4421S | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.017); catalogued as COSV100543225; called by muse, mutect2, varscan2
- DNM1 | c.715C>A p.Q239K | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV100359455; called by muse, mutect2
- DOCK4 | c.1556C>T p.P519L | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.739); catalogued as COSV101455441; called by muse, mutect2, varscan2
- DPEP1 | c.434C>A p.S145Y | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV55360180; called by muse, mutect2, varscan2
- DPY19L2 | c.2186C>A p.P729H | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as COSV100192734; called by muse, mutect2, varscan2
- DR1 | c.196A>G p.I66V | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100937773; called by muse, mutect2
- DSC3 | c.1069C>A p.Q357K | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs926301589, COSV100844486; called by muse, mutect2, varscan2
- DSCAML1 | c.3181C>A p.Q1061K (on ENST00000321322; = p.Q1001K on NM_020693.4) | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.242); catalogued as COSV100354521; called by muse, mutect2
- DST | c.20282G>T p.S6761I (on ENST00000361203 / NM_001374722.1; = p.S4458I on NM_015548.5) | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV99750893; called by muse, mutect2
- DST | c.17661G>C p.K5887N (on ENST00000361203 / NM_001374722.1; = p.K3584N on NM_015548.5) | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55033630; called by muse, mutect2, varscan2
- EFCAB11 | c.251G>T p.R84M | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.178); catalogued as COSV99965477; called by muse, mutect2, varscan2
- EFCAB6 | c.1729G>T p.V577F | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as COSV99412403; called by muse, mutect2, varscan2
- EOLA1 | c.28C>A p.Q10K | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as rs1557347582, COSV100828390; called by muse, mutect2, varscan2
- EPHA2 | c.1592G>C p.G531A | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV100626014; called by mutect2, varscan2
- EPHA5 | c.2643G>T p.E881D | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs372762875, COSV99896034; called by muse, mutect2, varscan2
- EVI5 | c.1617G>T p.W539C | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100945038; called by muse, mutect2, varscan2
- EXO1 | c.1964A>T p.K655M | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV100799607; called by muse, mutect2, varscan2
- EYA2 | c.523C>A p.P175T | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.067); catalogued as rs765002260, COSV100426475; called by muse, mutect2, varscan2
- F8 | c.1262C>A p.P421H | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.533); catalogued as COSV100811239; called by muse, mutect2, varscan2
- FAM135B | c.2825C>T p.A942V | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1197017156, COSV52757066, COSV99418655; called by muse, mutect2, varscan2
- FAM169A | c.253G>C p.D85H | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.139); catalogued as COSV100998299; called by muse, mutect2, varscan2
- FAM216A | c.487C>T p.Q163* | Nonsense Mutation (SNP) | VAF 29/107 reads (27%) | catalogued as COSV100862933; called by muse, mutect2, varscan2
- FANCL | c.427G>T p.A143S | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99287222; called by muse, mutect2, varscan2
- FAT3 | c.650G>T p.G217V | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99961712; called by muse, mutect2
- FBXO34 | c.1516T>A p.S506T | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as COSV100571835; called by muse, mutect2, varscan2
- FEM1B | c.791G>T p.R264L | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as rs1285173979, COSV100183541; called by muse, mutect2, varscan2
- FEM1B | c.1312G>T p.D438Y | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as rs781435603, COSV100183542; called by muse, mutect2, varscan2
- FFAR4 | c.608G>A p.G203E | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.644); catalogued as COSV101015593; called by muse, mutect2, varscan2
- FIG4 | c.2547-1G>A p.X849_splice | Splice Site (SNP) | VAF 10/50 reads (20%) | catalogued as rs769858739, CS1411824, COSV100019103; called by muse, mutect2
- FIGN | c.1082G>T p.R361L | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV100291469; called by muse, mutect2, varscan2
- FIGN | c.275C>T p.S92L | Missense Mutation (SNP) | VAF 15/149 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV60766130; called by muse, mutect2
- FLG | c.7333C>A p.Q2445K | Missense Mutation (SNP) | VAF 49/260 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.269); catalogued as COSV100910483; called by muse, mutect2, varscan2
- FLG | c.1484C>A p.S495* | Nonsense Mutation (SNP) | VAF 37/216 reads (17%) | catalogued as rs139321371, COSV100910484; called by muse, mutect2, varscan2
- FLNA | c.6647A>T p.Y2216F (on ENST00000369850 / NM_001110556.2; = p.Y2208F on NM_001456.3) | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.336); catalogued as COSV100774263; called by muse, mutect2, varscan2
- FLT3 | c.537G>T p.Q179H | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.164); catalogued as COSV99607314; called by muse, mutect2
- FMO2 | c.1218G>T p.M406I | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.059); catalogued as COSV99268880; called by muse, mutect2, varscan2
- FOXP3 | c.547C>A p.L183I | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.395); catalogued as COSV100873076; called by muse, mutect2, varscan2
- FRMPD1 | c.3370G>T p.V1124L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100899283; called by muse, mutect2, varscan2
- FRMPD1 | c.3997C>T p.Q1333* | Nonsense Mutation (SNP) | VAF 11/91 reads (12%) | catalogued as COSV100899284; called by muse, mutect2, varscan2
- FRMPD2 | c.1528C>A p.L510I | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.012); catalogued as COSV100563489, COSV59719114; called by muse, mutect2, varscan2
- FSCB | c.1466C>G p.A489G | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.58); catalogued as COSV100468832; called by muse, mutect2, varscan2
- FSHB | c.356C>G p.P119R | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99569311; called by muse, mutect2, varscan2
- FUCA1 | c.649G>T p.D217Y | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV100992122; called by muse, mutect2, varscan2
- FYB2 | c.620A>G p.H207R | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1475385685, COSV100599192; called by muse, mutect2, varscan2
- GABRA3 | c.85C>A p.Q29K | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT tolerated, low confidence (0.44); PolyPhen possibly damaging (0.678); catalogued as COSV100942428, COSV64799019; called by muse, mutect2, varscan2
- GALNT13 | c.858G>C p.R286S | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.65); catalogued as COSV101222170, COSV67233749; called by muse, mutect2
- GALR1 | c.214C>A p.L72M | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV100231648; called by muse, mutect2, varscan2
- GARS1 | c.882-2A>G p.X294_splice | Splice Site (SNP) | VAF 16/64 reads (25%) | catalogued as rs1280433206, COSV101219941; called by muse, mutect2, varscan2
- GCNA | c.1592G>T p.R531I | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); catalogued as COSV101032381; called by mutect2, varscan2
- GKN1 | c.430G>A p.G144R | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100933534; called by muse, mutect2, varscan2
- GLE1 | c.1288G>T p.V430L | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.93); catalogued as COSV100012316; called by muse, mutect2, varscan2
- GLT8D1 | c.362T>A p.I121N | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV99803503; called by muse, mutect2, varscan2
- GPR101 | c.1003G>T p.D335Y | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.382); catalogued as COSV99981249; called by muse, mutect2, varscan2
- GPR141 | c.895T>A p.W299R | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.823); catalogued as COSV100550215; called by muse, mutect2, varscan2
- GPRIN3 | c.1546G>T p.G516C | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.874); catalogued as COSV100310575; called by muse, mutect2, varscan2
- GRHL1 | c.208G>T p.V70F | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100257490, COSV100258108; called by muse, mutect2
- GRIA3 | c.268+2T>C p.X90_splice | Splice Site (SNP) | VAF 15/120 reads (13%) | catalogued as COSV99988908; called by muse, mutect2, varscan2
- GRIN2A | c.1240G>T p.A414S | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.047); catalogued as COSV100408218, COSV58031666; called by muse, mutect2, varscan2
- HDAC1 | c.935G>T p.W312L | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100269480; called by muse, mutect2
- HPD | c.75G>T p.W25C | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100000000; called by mutect2, varscan2
- HPS5 | c.841G>C p.D281H (on ENST00000349215 / NM_181507.2; = p.D167H on NM_007216.4) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV100834336; called by muse, mutect2, varscan2
- HPSE2 | c.838G>T p.G280* | Nonsense Mutation (SNP) | VAF 23/103 reads (22%) | catalogued as COSV100984882; called by muse, mutect2, varscan2
- HRG | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 4/63 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV99214541; called by muse, mutect2
- HRNR | c.1227C>A p.H409Q | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1022476504, COSV100912899; called by muse, mutect2, varscan2
- HSF2BP | c.442-1G>C p.X148_splice | Splice Site (SNP) | VAF 8/40 reads (20%) | catalogued as COSV99375210; called by muse, mutect2, varscan2
- IGSF11 | c.331C>G p.Q111E (on ENST00000393775 / NM_001015887.3; = p.Q110E on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.561); catalogued as COSV61178304; called by muse, mutect2, varscan2
- IGSF5 | c.1129-2A>T p.X377_splice | Splice Site (SNP) | VAF 8/30 reads (27%) | catalogued as rs1285796727, COSV101011972; called by muse, mutect2, varscan2
- IKBKB | c.1688+2T>C p.X563_splice | Splice Site (SNP) | VAF 8/41 reads (20%) | catalogued as rs759240761, COSV100645576; called by muse, mutect2, varscan2
- IL1RL2 | c.1439G>T p.G480V | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769124849, COSV99960205; called by muse, varscan2
- IL31RA | c.2233G>T p.V745L | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as COSV100732433, COSV100732982; called by muse, mutect2, varscan2
- IL36A | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 7/41 reads (17%) | catalogued as COSV99382031, COSV99382037; called by muse, mutect2, varscan2
- INSYN2A | c.194C>A p.S65Y | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV99726722; called by muse, mutect2, varscan2
- IPO13 | c.963-1G>T p.X321_splice | Splice Site (SNP) | VAF 12/56 reads (21%) | catalogued as COSV100961040; called by muse, mutect2, varscan2
- IRF8 | c.499G>T p.E167* | Nonsense Mutation (SNP) | VAF 14/73 reads (19%) | catalogued as COSV51900523, COSV99236027; called by muse, mutect2, varscan2
- IRX5 | c.335G>T p.G112V | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100315616; called by muse, mutect2, varscan2
- ITGA4 | c.450T>A p.N150K | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51997926, COSV99275717; called by muse, mutect2, varscan2
- ITGAM | c.1585G>T p.G529W (on ENST00000648685 / NM_001145808.2; = p.G528W on NM_000632.4) | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99791751; called by muse, mutect2, varscan2
- ITPRID2 | c.3641T>C p.V1214A | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.654); catalogued as COSV100237857; called by muse, mutect2, varscan2
- KAT14 | c.2070G>C p.M690I | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV100890030; called by muse, mutect2, varscan2
- KBTBD7 | c.251G>A p.C84Y | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101068017; called by muse, mutect2
- KCND1 | c.550G>T p.A184S | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV54416397, COSV99501697; called by muse, mutect2, varscan2
- KCNK9 | c.526G>T p.A176S | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as COSV100270307, COSV57279203; called by muse, mutect2
- KIF13A | c.3937A>T p.K1313* | Nonsense Mutation (SNP) | VAF 5/22 reads (23%) | catalogued as COSV99433715; called by muse, mutect2, varscan2
- KIF25 | c.229G>T p.G77* | Nonsense Mutation (SNP) | VAF 7/36 reads (19%) | catalogued as COSV100596231, COSV100596413; called by muse, mutect2, varscan2
- KIRREL2 | c.722G>T p.G241V | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99383530; called by muse, mutect2, varscan2
- KLF17 | c.532C>A p.P178T | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.242); catalogued as COSV100954795, COSV64856420; called by mutect2, varscan2
- KLF17 | c.1006del p.V336Yfs*18 | Frame Shift Del (DEL) | VAF 18/76 reads (24%) | catalogued as COSV64857108; called by mutect2, pindel, varscan2
- KLHL40 | c.58C>A p.Q20K | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs1292866391, COSV99825318; called by muse, mutect2, varscan2
- KNG1 | c.1834C>A p.P612T | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV99405094; called by muse, mutect2, varscan2
- KNG1 | c.1835C>A p.P612Q | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.766); catalogued as COSV99405097; called by muse, mutect2, varscan2
- KNOP1 | c.715C>A p.P239T | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as COSV99575043; called by muse, mutect2, varscan2
- KRT38 | c.1052C>A p.A351D | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.416); catalogued as COSV99878074; called by muse, mutect2, varscan2
- KRT40 | c.784C>T p.R262C | Missense Mutation (SNP) | VAF 34/180 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770104419, COSV100898772; called by muse, mutect2, varscan2
- KRTAP5-3 | c.708C>A p.C236* | Nonsense Mutation (SNP) | VAF 24/130 reads (18%) | catalogued as COSV101294488; called by muse, mutect2, varscan2
- KRTAP9-9 | c.374G>C p.G125A | Missense Mutation (SNP) | VAF 33/172 reads (19%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.941); catalogued as COSV101223479; called by muse, mutect2, varscan2
- KYAT3 | c.57G>T p.K19N | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.521); catalogued as COSV99555447; called by muse, mutect2, varscan2
- LAMA2 | c.909T>G p.N303K | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.063); catalogued as COSV101369977, COSV101370271; called by muse, mutect2, varscan2
- LAMB4 | c.4153G>T p.V1385L | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.026); catalogued as rs1393675929, COSV52719860; called by muse, mutect2, varscan2
- LARP1 | c.2335A>T p.N779Y (on ENST00000518297 / NM_033551.3; = p.N702Y on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.345); catalogued as COSV100303384; called by muse, mutect2, varscan2
- LCLAT1 | c.279G>T p.V93= | Splice Region (SNP) | VAF 15/60 reads (25%) | catalogued as rs1191754066, COSV100091935, COSV58373505; called by muse, mutect2, varscan2
- LGI2 | c.798C>A p.F266L | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.277); catalogued as COSV101180742; called by muse, mutect2, varscan2
- LHX4 | c.103C>A p.Q35K | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.1); catalogued as COSV55377336; called by muse, mutect2, varscan2
- LIMA1 | c.227G>T p.W76L | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100372194; called by muse, mutect2, varscan2
- LINS1 | c.952G>T p.G318* | Nonsense Mutation (SNP) | VAF 8/51 reads (16%) | catalogued as COSV100129946; called by muse, mutect2, varscan2
- LPAR3 | c.562C>A p.L188I | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1481449542, COSV101004669; called by muse, mutect2, varscan2
- LRFN3 | c.593G>T p.G198V | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99873102; called by muse, mutect2, varscan2
- LRRC30 | c.503T>G p.L168R | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101274368; called by muse, mutect2, varscan2
- LRRC7 | c.4359G>C p.Q1453H (on ENST00000651989 / NM_001370785.2; = p.Q1373H on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV99224388; called by muse, mutect2, varscan2
- LRRTM1 | c.247G>T p.G83C | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.992); catalogued as COSV54445793, COSV99701744; called by muse, mutect2
- LRRTM4 | c.1126C>A p.Q376K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101297418; called by muse, mutect2, varscan2
- LTBP2 | c.2953T>A p.C985S | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99999665; called by muse, mutect2, varscan2
- LZTS1 | c.1586G>T p.R529L | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99742640; called by muse, mutect2, varscan2
- MACF1 | c.13797G>T p.M4599I (on ENST00000372915; = p.M2532I on NM_012090.5) | Missense Mutation (SNP) | VAF 5/37 reads (14%) | catalogued as COSV99241075; called by muse, mutect2, varscan2
- MAGEC2 | c.619G>T p.V207L | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); catalogued as COSV99909379, COSV99909561; called by muse, mutect2, varscan2
- MAGEE1 | c.2428C>T p.H810Y | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.25); catalogued as COSV100819260; called by muse, mutect2, varscan2
- MAGI2 | c.2630G>T p.G877V | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.674); catalogued as rs1191450572, COSV100832688; called by muse, mutect2, varscan2
- MAGI2 | c.2629G>T p.G877C | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as COSV100832690; called by muse, mutect2, varscan2
- MAP2 | c.4402G>T p.A1468S | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.455); catalogued as rs759447374, COSV52293623; called by muse, mutect2, varscan2
- MAP2K3 | c.70G>T p.D24Y | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs953801481, COSV57569276; called by muse, mutect2, varscan2
- MAP7D2 | c.314A>T p.E105V | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV101107155; called by muse, mutect2, varscan2
- ME1 | c.635G>T p.R212L | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.695); catalogued as COSV100866321; called by muse, mutect2, varscan2
- MED8 | c.153G>T p.L51F | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99318294; called by muse, mutect2, varscan2
- METAP2 | c.294G>T p.K98N | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as COSV99704637; called by muse, mutect2
- MMP16 | c.446G>T p.R149L | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.02); catalogued as COSV54149337; called by muse, mutect2, varscan2
- MMRN1 | c.2921A>T p.K974I | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99306402; called by muse, mutect2, varscan2
- MNS1 | c.865C>A p.Q289K | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT tolerated (0.66); PolyPhen benign (0.009); catalogued as COSV99549362; called by muse, mutect2
- MORC1 | c.1390G>C p.E464Q | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.027); catalogued as COSV99225012; called by muse, mutect2
- MPEG1 | c.1616C>A p.P539H | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99914979; called by muse, mutect2, varscan2
- MRGPRX2 | c.379C>A p.R127S | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV100316619, COSV61675033; called by muse, mutect2, varscan2
- MRPL21 | c.448G>T p.G150* | Nonsense Mutation (SNP) | VAF 4/25 reads (16%) | catalogued as COSV62913845; called by muse, mutect2, varscan2
- MRPS2 | c.827A>G p.Q276R | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV99613236; called by muse, mutect2, varscan2
- MS4A13 | c.450C>A p.S150R | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.11); catalogued as rs1380532422, COSV100981027, COSV65446362; called by muse, mutect2, varscan2
- MS4A6A | c.71C>A p.A24E | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.236); catalogued as rs778801218, COSV100124529; called by muse, mutect2, varscan2
- MTMR1 | c.735T>A p.S245R | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV100953056, COSV64892870; called by muse, mutect2, varscan2
- MUC16 | c.42653C>A p.P14218H | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV101109581, COSV66690346; called by muse, mutect2, varscan2
- MUC16 | c.15155C>A p.P5052H | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.959); catalogued as COSV101198071; called by muse, mutect2, varscan2
- MUC17 | c.9019C>A p.L3007I | Missense Mutation (SNP) | VAF 52/334 reads (16%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.636); catalogued as COSV100071552; called by muse, varscan2
- MVP | c.2540G>T p.G847V | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1341375635, COSV100651473, COSV62422092; called by muse, mutect2, varscan2
- MXRA5 | c.913C>A p.Q305K | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as COSV99475677; called by muse, mutect2, varscan2
- MYH1 | c.2229G>T p.K743N | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99874851; called by muse, mutect2, varscan2
- MYH13 | c.3415C>A p.Q1139K | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.515); catalogued as COSV99352217; called by muse, mutect2, varscan2
- MYH3 | c.71G>C p.R24T | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.312); catalogued as COSV99877695; called by muse, mutect2, varscan2
- MYO18B | c.6710del p.P2237Rfs*36 | Frame Shift Del (DEL) | VAF 4/16 reads (25%) | catalogued as COSV59133064; called by mutect2, varscan2
- MYO1H | c.940C>A p.H314N | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100183084; called by muse, varscan2
- MYOM3 | c.2212C>A p.Q738K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.92); catalogued as COSV100292431; called by mutect2, varscan2
- MYPN | c.274G>T p.D92Y | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV100589509, COSV100590131; called by muse, mutect2, varscan2
- NAA16 | c.2441G>T p.G814V | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101049736; called by muse, mutect2
- NAV3 | c.2375G>T p.R792M | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV99886810; called by muse, mutect2, varscan2
- NEDD4L | c.663G>T p.W221C | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56843671, COSV99893350; called by muse, mutect2, varscan2
- NF1 | c.3871-2A>T p.X1291_splice | Splice Site (SNP) | VAF 10/47 reads (21%) | catalogued as COSV100645998; called by muse, mutect2, varscan2
- NHSL2 | c.1126G>T p.V376F (on ENST00000510661; = p.V742F on NM_001013627.2) | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.773); catalogued as COSV65455091, COSV65455173; called by muse, mutect2
- NKX6-1 | c.719G>T p.R240I | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99879904; called by muse, mutect2, varscan2
- NLRP14 | c.3069G>T p.Q1023H | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.359); catalogued as COSV100204529, COSV55067997; called by muse, mutect2, varscan2
- NPHP4 | c.1112A>G p.D371G | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.453); catalogued as COSV100976714; called by muse, mutect2, varscan2
- NR3C1 | c.2189A>G p.E730G | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs1458571496, COSV99196076; called by muse, mutect2
- NR5A2 | c.1181A>T p.Q394L (on ENST00000367362 / NM_205860.3; = p.Q348L on NM_003822.5) | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV99370633; called by muse, mutect2, varscan2
- NRG3 | c.1333G>T p.E445* | Nonsense Mutation (SNP) | VAF 8/36 reads (22%) | catalogued as COSV100930654, COSV100932530; called by muse, mutect2, varscan2
- NRXN1 | c.2840G>A p.G947E | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100453190; called by muse, mutect2, varscan2
- OR10W1 | c.155A>T p.Y52F | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101223606; called by muse, mutect2, varscan2
- OR13C2 | c.853G>T p.G285W | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV73377830; called by muse, mutect2, varscan2
- OR13C3 | c.862A>T p.M288L | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV101053255; called by muse, mutect2
- OR1L4 | c.89C>A p.A30D | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.28); catalogued as COSV99413770; called by muse, mutect2
- OR1S1 | c.154G>T p.V52L | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.1); catalogued as COSV58707509; called by muse, mutect2, varscan2
- OR2L8 | c.44G>T p.G15V | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100594020; called by muse, mutect2, varscan2
- OR2M5 | c.263G>T p.G88V | Missense Mutation (SNP) | VAF 42/242 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as rs1326812116, COSV100822738, COSV63546740; called by muse, mutect2, varscan2
- OR4A15 | c.640C>A p.L214I | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.01); catalogued as rs751294933, COSV59035083; called by muse, mutect2, varscan2
- OR4A16 | c.181C>A p.L61I | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV100125008; called by muse, mutect2, varscan2
- OR4C15 | c.630G>T p.M210I (on ENST00000314644; = p.M156I on NM_001001920.2) | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs1471878131, COSV100115359, COSV58952128; called by muse, mutect2, varscan2
- OR4D9 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755732245, COSV61434120; called by muse, mutect2, varscan2
- OR5B3 | c.100A>G p.I34V | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as COSV100511853; called by muse, mutect2, varscan2
- OR5D14 | c.830C>G p.S277C | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); catalogued as COSV100162107, COSV59458231; called by muse, mutect2, varscan2
- OR7D4 | c.335C>A p.T112N | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100432588; called by muse, mutect2, varscan2
- OR8B12 | c.163C>A p.H55N | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.616); catalogued as COSV100172632; called by muse, mutect2, varscan2
- ORC4 | c.57+1G>T p.X19_splice | Splice Site (SNP) | VAF 7/53 reads (13%) | catalogued as COSV99931959; called by muse, mutect2, varscan2
- OTUD7A | c.1630G>T p.G544C (on ENST00000307050 / NM_001382637.1; = p.G537C on NM_130901.3) | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1466592678, COSV100191871; called by muse, mutect2
- P2RY8 | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768881939, COSV101183933; called by muse, mutect2, varscan2
- PACSIN1 | c.529A>T p.S177C | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV55060359, COSV99762857; called by mutect2, varscan2
- PADI2 | c.1188G>C p.E396D | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.468); catalogued as COSV100970846, COSV64946715; called by muse, mutect2, varscan2
- PAGE3 | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV100891963; called by muse, mutect2, varscan2
- PALLD | c.534G>T p.E178D | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99823819; called by muse, mutect2
- PAPOLB | c.1226A>T p.N409I | Missense Mutation (SNP) | VAF 34/205 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV101271249; called by muse, mutect2, varscan2
- PAPPA2 | c.690G>T p.R230S | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.041); catalogued as COSV100866531, COSV100866580; called by muse, mutect2, varscan2
- PAX5 | c.934C>T p.L312F | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100814023; called by muse, mutect2, varscan2
- PCDHA2 | c.757G>T p.E253* | Nonsense Mutation (SNP) | VAF 19/68 reads (28%) | catalogued as COSV100973552; called by muse, mutect2, varscan2
- PCDHA5 | c.1162C>A p.L388I | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.767); catalogued as COSV100972085; called by muse, mutect2, varscan2
- PCDHA7 | c.352C>A p.H118N | Missense Mutation (SNP) | VAF 39/171 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.805); catalogued as COSV100971220, COSV100971678; called by muse, mutect2, varscan2
- PCDHA9 | c.2368T>A p.S790T | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.045); catalogued as COSV100969008; called by muse, mutect2, varscan2
- PCDHGA10 | c.193G>T p.E65* | Nonsense Mutation (SNP) | VAF 24/88 reads (27%) | catalogued as COSV53978897, COSV99530329; called by muse, mutect2, varscan2
- PCDHGB1 | c.124G>C p.G42R | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54012625, COSV99530321, COSV99546418; called by muse, mutect2, varscan2
- PCDHGB1 | c.1081G>C p.V361L | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.029); catalogued as COSV99530322; called by muse, mutect2, varscan2
- PCDHGB5 | c.1868G>T p.R623L | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1042095164, COSV53908465; called by muse, mutect2, varscan2
- PCK1 | c.273G>T p.K91N | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV100099965; called by mutect2, varscan2
- PCK1 | c.799-1G>T p.X267_splice | Splice Site (SNP) | VAF 3/38 reads (8%) | catalogued as COSV60126129; called by muse, mutect2
- PCLO | c.7498A>T p.T2500S | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.99); PolyPhen benign (0.027); catalogued as COSV100427237; called by muse, mutect2, varscan2
- PDE10A | c.1684T>G p.C562G | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100604380; called by muse, mutect2, varscan2
- PDE1C | c.803A>G p.H268R | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs776550904, COSV100370811; called by muse, mutect2, varscan2
- PF4V1 | c.281A>T p.Y94F | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.828); catalogued as COSV99896289; called by muse, mutect2, varscan2
- PFAS | c.1843G>T p.D615Y | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); catalogued as rs747381940, COSV100118744, COSV58979011; called by muse, mutect2
- PHC2 | c.2494G>T p.D832Y (on ENST00000257118 / NM_198040.2; = p.D297Y on NM_004427.4) | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57105573; called by muse, mutect2
- PI15 | c.170G>T p.R57M | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52641189, COSV99477782; called by muse, mutect2, varscan2
- PIP4K2C | c.744G>C p.K248N | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as COSV100533374; called by muse, mutect2
- PLEKHG4B | c.3497-1G>T p.X1166_splice (on ENST00000283426; = p.X1522_splice on NM_052909.5) | Splice Site (SNP) | VAF 5/56 reads (9%) | catalogued as COSV99359767; called by muse, mutect2
- PLG | c.408-2A>G p.X136_splice | Splice Site (SNP) | VAF 7/43 reads (16%) | catalogued as COSV99804225; called by muse, mutect2, varscan2
- PLPPR4 | c.2127G>T p.E709D | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV100926690; called by muse, mutect2
- PLXNA4 | c.4641A>T p.K1547N | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); catalogued as COSV100322381; called by muse, mutect2, varscan2
- PMFBP1 | c.86T>C p.L29P | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99400133; called by muse, mutect2, varscan2
- POLR3C | c.56A>G p.E19G | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as COSV100492763; called by muse, mutect2, varscan2
- POTEE | c.330G>T p.R110S | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.227); catalogued as COSV58246696; called by muse, mutect2
- PPARGC1A | c.2371G>T p.E791* | Nonsense Mutation (SNP) | VAF 7/55 reads (13%) | catalogued as COSV99337210; called by muse, mutect2, varscan2
- PPP1R36 | c.637G>C p.V213L | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs751571174, COSV100072673; called by muse, mutect2, varscan2
- PPP2CA | c.577G>T p.G193C | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1266057067, COSV99196019; called by muse, mutect2, varscan2
- PREX1 | c.560C>A p.P187H | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1328157531, COSV100906055; called by muse, mutect2, varscan2
- PRICKLE1 | c.2094G>T p.K698N | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as COSV100453444; called by muse, mutect2, varscan2
- PRR23B | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.234); catalogued as COSV61494310; called by muse, mutect2, varscan2
- PRSS37 | c.83C>A p.P28H | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100633791; called by mutect2, varscan2
- PTF1A | c.81C>A p.F27L | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.026); catalogued as rs766603590, COSV100919564; called by muse, mutect2, varscan2
- PTGER4 | c.913G>C p.E305Q | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.012); catalogued as COSV100201400; called by muse, mutect2, varscan2
- PTH1R | c.1508C>A p.T503K | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as COSV100480794; called by muse, mutect2, varscan2
- PTK2 | c.2459A>T p.E820V | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100569334; called by muse, mutect2, varscan2
- PXDNL | c.3361G>T p.E1121* | Nonsense Mutation (SNP) | VAF 12/58 reads (21%) | catalogued as COSV100681207; called by muse, mutect2, varscan2
- PXDNL | c.3204T>G p.N1068K | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100681213; called by muse, mutect2, varscan2
- PYHIN1 | c.497G>T p.G166V | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.098); catalogued as COSV100932311; called by muse, mutect2, varscan2
- RALA | c.393A>T p.L131F | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99143329; called by muse, mutect2
- RASA2 | c.1348G>A p.E450K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.889); catalogued as COSV99655590; called by muse, mutect2, varscan2
- RBM43 | c.487A>T p.R163* | Nonsense Mutation (SNP) | VAF 17/110 reads (15%) | catalogued as COSV100508457; called by muse, mutect2, varscan2
- RBM43 | c.328G>T p.V110L | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); catalogued as COSV100508459; called by muse, mutect2, varscan2
- RBM48 | c.655G>T p.D219Y | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV99720037; called by muse, mutect2, varscan2
- REG3G | c.67C>G p.Q23E | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV99709203; called by muse, mutect2, varscan2
- RGS21 | c.363G>T p.K121N | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.04); catalogued as COSV101313979, COSV69883991; called by muse, mutect2, varscan2
- RGS21 | c.364G>T p.D122Y | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101313980; called by muse, mutect2, varscan2
- RHNO1 | c.149A>T p.H50L | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.219); catalogued as COSV100817011; called by muse, mutect2, varscan2
- RIMS2 | c.1022G>T p.R341L (on ENST00000666250 / NM_001348490.2; = p.R149L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1459469823, COSV51696368, COSV99158649; called by muse, mutect2, varscan2
- RNF144A | c.428G>T p.C143F | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100305268; called by muse, mutect2, varscan2
- ROBO2 | c.74G>C p.R25P | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100164099, COSV59949799; called by muse, mutect2
- ROBO3 | c.794T>G p.V265G | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV101184899; called by muse, mutect2, varscan2
- ROPN1B | c.631C>G p.L211V | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV99305461; called by muse, mutect2, varscan2
- ROR2 | c.2614G>T p.G872C | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100995472; called by muse, mutect2, varscan2
- RP1L1 | c.1469G>T p.G490V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV66758858; called by muse, mutect2, varscan2
- RPL14 | c.25G>T p.V9F | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV100166122; called by muse, mutect2, varscan2
- RUBCN | c.2685G>T p.Q895H | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.972); catalogued as COSV99583160, COSV99584496; called by muse, mutect2
- RUBCN | c.77G>T p.W26L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV99583162; called by muse, mutect2, varscan2
- RYR1 | c.166-2A>T p.X56_splice | Splice Site (SNP) | VAF 12/46 reads (26%) | catalogued as COSV100614382; called by muse, mutect2, varscan2
- RYR2 | c.6040G>T p.D2014Y | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.423); catalogued as COSV100767713; called by muse, mutect2
- RYR3 | c.9694G>A p.E3232K (on ENST00000389232; = p.E3233K on NM_001036.6) | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101211961; called by muse, mutect2, varscan2
- RYR3 | c.9814G>T p.V3272L (on ENST00000389232; = p.V3273L on NM_001036.6) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV101211962, COSV101213184; called by muse, mutect2, varscan2
- S100A7L2 | c.220G>T p.E74* | Nonsense Mutation (SNP) | VAF 12/53 reads (23%) | catalogued as COSV100906845; called by muse, mutect2, varscan2
- S1PR5 | c.1136C>A p.T379K | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as rs1466693321, COSV100330672; called by muse, mutect2, varscan2
- SACS | c.1370G>T p.S457I | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV101207167; called by muse, mutect2
- SCN3A | c.5353C>A p.L1785M | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99325608; called by muse, mutect2, varscan2
- SCN8A | c.3212G>T p.G1071V | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV100633210; called by muse, mutect2, varscan2
- SELP | c.2011G>T p.G671C | Missense Mutation (SNP) | VAF 45/247 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as COSV99738946; called by muse, mutect2, varscan2
- SEMA3A | c.508C>A p.P170T | Missense Mutation (SNP) | VAF 43/200 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99545197; called by muse, mutect2, varscan2
- SERPINB10 | c.65C>A p.S22Y | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV99448737; called by muse, mutect2, varscan2
- SGK2 | c.958G>T p.A320S | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.145); catalogued as COSV100414552; called by muse, varscan2
- SHMT2 | c.1160G>T p.R387L | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100196959, COSV61075219; called by muse, mutect2, varscan2
- SIPA1L2 | c.3643-1G>C p.X1215_splice | Splice Site (SNP) | VAF 6/60 reads (10%) | catalogued as COSV99477104; called by muse, mutect2
- SLBP | c.637G>T p.V213L | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.084); catalogued as COSV100571332; called by muse, mutect2, varscan2
- SLC26A7 | c.721C>A p.L241I | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99402505, COSV99404289; called by muse, mutect2, varscan2
- SLC27A6 | c.1142G>C p.G381A | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs900563973, COSV52487120, COSV99322106, COSV99323316; called by muse, mutect2, varscan2
- SLC28A1 | c.325G>T p.A109S | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as rs1301490340, COSV99722531; called by muse, mutect2, varscan2
- SLC3A1 | c.809G>T p.R270L | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs142358712, CM983885, COSV99576814; called by muse, mutect2, varscan2
- SLC4A10 | c.356C>A p.T119K | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV99762336; called by muse, mutect2, varscan2
- SLC4A8 | c.1885G>T p.D629Y | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV100176426; called by muse, mutect2, varscan2
- SLC6A17 | c.1538A>C p.Q513P | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100521081; called by muse, mutect2, varscan2
- SLC6A7 | c.343T>A p.F115I | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV100045950; called by muse, mutect2
- SLC8A1 | c.1906G>C p.E636Q | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV100244422, COSV60484520; called by muse, mutect2, varscan2
- SLCO1C1 | c.1536T>A p.S512R | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (0.23); PolyPhen benign (0.022); catalogued as COSV99858450; called by muse, mutect2, varscan2
- SLITRK6 | c.2020T>A p.S674T | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV101233176; called by muse, mutect2, varscan2
- SMG1 | c.9645G>T p.M3215I | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV101245119; called by muse, mutect2
- SMTNL2 | c.677G>A p.G226D (on ENST00000389313 / NM_001114974.2; = p.G82D on NM_198501.3) | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as rs746029642, COSV100130507; called by muse, mutect2, varscan2
- SNTB1 | c.980G>T p.G327V | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1398375221, COSV101179716, COSV67330061; called by muse, mutect2, varscan2
- SOGA3 | c.1360G>T p.E454* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as rs1301986607, COSV64105023; called by muse, mutect2, varscan2
- SORCS1 | c.1059T>A p.C353* | Nonsense Mutation (SNP) | VAF 8/63 reads (13%) | catalogued as COSV99543134; called by muse, mutect2, varscan2
- SOWAHD | c.917G>T p.R306L | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as rs1362515029, COSV100673110, COSV59649759; called by muse, mutect2, varscan2
- SPAG8 | c.12C>A p.N4K | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV99427836; called by muse, mutect2, varscan2
- SPATA31D1 | c.3815C>T p.P1272L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.318); catalogued as rs1170621158, COSV100782458; called by muse, mutect2, varscan2
- SPOCK3 | c.716G>T p.S239I | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.757); catalogued as rs1447961058, COSV100691824, COSV100694310; called by muse, mutect2, varscan2
- SRP54 | c.1271A>G p.Y424C | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99392396; called by muse, mutect2, varscan2
- SSMEM1 | c.88T>A p.W30R | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV99927576; called by muse, mutect2, varscan2
- STAB2 | c.516C>A p.N172K | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.221); catalogued as COSV101185608; called by muse, mutect2, varscan2
- STAG2 | c.547G>T p.V183L | Missense Mutation (SNP) | VAF 39/272 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.363); catalogued as COSV99492235; called by muse, mutect2, varscan2
- STAM2 | c.981A>T p.Q327H | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV99812842; called by muse, mutect2
- STAT6 | c.149G>T p.C50F | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.023); catalogued as COSV100273062; called by muse, mutect2, varscan2
- STK31 | c.2395T>G p.C799G | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.192); catalogued as COSV100669106; called by muse, mutect2, varscan2
- STYXL1 | c.456A>T p.E152D | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as COSV99951236; called by muse, mutect2, varscan2
- SYN1 | c.958G>A p.G320R | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99927061; called by muse, mutect2, varscan2
- SYNCRIP | c.1543G>T p.A515S | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV100783990; called by muse, mutect2, varscan2
- SYNGR4 | c.272C>G p.T91S | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV100785097, COSV100785106; called by muse, mutect2, varscan2
- SYT11 | c.462G>T p.E154D | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100851269; called by muse, mutect2, varscan2
- TAB3 | c.1772C>A p.T591K | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV99915724; called by muse, mutect2, varscan2
- TAC1 | c.52T>C p.F18L | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs774315492, COSV100071027; called by muse, mutect2, varscan2
- TAC3 | c.77C>A p.P26Q | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.162); catalogued as rs1257505387, COSV100269799; called by muse, mutect2, varscan2
- TAF1L | c.2863A>G p.R955G | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.434); catalogued as rs1168633666, COSV99644079; called by muse, mutect2, varscan2
- TAF4 | c.3134G>T p.G1045V | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV99433433; called by muse, mutect2, varscan2
- TANC1 | c.1369G>T p.D457Y | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV99713050; called by muse, mutect2, varscan2
- TBC1D19 | c.433+1G>T p.X145_splice | Splice Site (SNP) | VAF 6/14 reads (43%) | catalogued as rs774302573, COSV53516314, COSV99335924; called by muse, mutect2, varscan2
- TCAF1 | c.331G>T p.D111Y | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as COSV100584548; called by mutect2, varscan2
- TENM1 | c.3610C>A p.P1204T | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV100948980, COSV100949424; called by muse, mutect2, varscan2
- TENT5D | c.895C>A p.L299I | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100382541; called by muse, mutect2, varscan2
- TEX13B | c.764G>T p.W255L | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.844); catalogued as COSV100258242; called by muse, mutect2, varscan2
- TFAP2B | c.1366G>T p.E456* | Nonsense Mutation (SNP) | VAF 5/26 reads (19%) | catalogued as COSV99539630; called by muse, mutect2
- TFAP2D | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.444); catalogued as rs992510064, COSV50425176, COSV99145679; called by muse, mutect2, varscan2
- THSD7B | c.658C>G p.L220V | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55744931, COSV99744113; called by muse, mutect2, varscan2
- TIGAR | c.277G>T p.G93W | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99463315; called by muse, mutect2, varscan2
- TMC7 | c.1628A>T p.N543I | Missense Mutation (SNP) | VAF 54/218 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100432266; called by muse, mutect2, varscan2
- TMEM132D | c.2269G>C p.A757P | Missense Mutation (SNP) | VAF 4/67 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as COSV101242539; called by muse, mutect2
- TMEM164 | c.88G>T p.A30S | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.223); catalogued as COSV99911333; called by muse, mutect2, varscan2
- TMEM184B | c.861G>T p.E287D | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.044); catalogued as rs1399558353, COSV100725893; called by muse, mutect2
- TMEM215 | c.353G>T p.R118M | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.575); catalogued as COSV100713134; called by muse, mutect2, varscan2
- TMPRSS15 | c.1067G>T p.W356L | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99516795; called by muse, mutect2, varscan2
- TMTC1 | c.447G>C p.L149F (on ENST00000539277 / NM_001193451.2; = p.L41F on NM_175861.3) | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99758664; called by muse, mutect2, varscan2
- TMTC3 | c.1792G>C p.D598H | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99898028; called by muse, mutect2, varscan2
- TPH2 | c.849C>G p.S283R | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV100421881; called by muse, mutect2, varscan2
- TRHDE | c.1105G>T p.A369S | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as COSV99669032; called by muse, mutect2, varscan2
- TRIM9 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 51/154 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.101); catalogued as COSV100030439; called by muse, mutect2, varscan2
- TRIML1 | c.1002G>T p.Q334H | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100205690; called by muse, mutect2, varscan2
- TRIOBP | c.3352G>T p.D1118Y | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); catalogued as COSV100730578; called by muse, mutect2, varscan2
- TRO | c.1369G>T p.V457F | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV99435733; called by muse, mutect2, varscan2
- TRPA1 | c.724C>A p.P242T | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100083134; called by muse, mutect2, varscan2
- TRPC3 | c.675G>T p.E225D (on ENST00000379645 / NM_001366479.2; = p.E152D on NM_003305.2) | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.826); catalogued as COSV99312093; called by muse, mutect2, varscan2
- TRPM3 | c.1189G>T p.V397L (on ENST00000357533 / NM_001366142.2; = p.V242L on NM_020952.6) | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as COSV100676578; called by muse, mutect2, varscan2
- TRPM8 | c.3231-2A>T p.X1077_splice | Splice Site (SNP) | VAF 6/72 reads (8%) | catalogued as COSV100223562; called by muse, mutect2
- TSGA10 | c.653A>T p.Q218L | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV100747428; called by muse, mutect2, varscan2
- TTC3 | c.4026G>T p.L1342F | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.36); catalogued as rs746033406, COSV61295692; called by muse, mutect2, varscan2
- TTN | c.47125A>T p.K15709* (on ENST00000591111; = p.K8285* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 5/18 reads (28%) | catalogued as COSV100593459; called by muse, mutect2, varscan2
- TYRO3 | c.743G>T p.G248V | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99777161; called by muse, mutect2, varscan2
- UGT2A3 | c.1276G>T p.A426S | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.691); catalogued as COSV99279584; called by muse, mutect2
- UGT2B28 | c.44G>T p.G15V | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1407880788, COSV100158544, COSV59431393; called by muse, mutect2, varscan2
- UNC79 | c.3486C>A p.S1162R (on ENST00000393151 / NM_001346218.2; = p.S985R on NM_020818.5) | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV99825701; called by muse, mutect2, varscan2
- UQCRH | c.28C>A p.L10I | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV100295492; called by muse, mutect2, varscan2
- USH2A | c.14488T>A p.S4830T | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.053); catalogued as COSV100228760; called by muse, mutect2, varscan2
- USP34 | c.8114G>T p.R2705M | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV101276641; called by muse, mutect2, varscan2
- UTS2B | c.335C>A p.A112D | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1361160192, COSV100484055; called by muse, mutect2, varscan2
- UVRAG | c.883G>T p.E295* | Nonsense Mutation (SNP) | VAF 14/88 reads (16%) | catalogued as COSV100638115; called by muse, mutect2, varscan2
- VEPH1 | c.1120A>T p.S374C | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.315); catalogued as COSV100747348; called by muse, mutect2, varscan2
- VPS13D | c.3057G>T p.L1019F | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99165433; called by muse, mutect2, varscan2
- VWF | c.4298C>A p.P1433H | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99777918; called by muse, mutect2, varscan2
- WWC3 | c.3262C>A p.P1088T | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.681); catalogued as COSV101080994; called by muse, mutect2, varscan2
- WWP1 | c.1498G>T p.E500* | Nonsense Mutation (SNP) | VAF 11/43 reads (26%) | catalogued as COSV99615568; called by muse, mutect2, varscan2
- XPNPEP2 | c.1568G>A p.G523D | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100941397; called by muse, mutect2, varscan2
- ZBTB33 | c.869C>A p.T290K | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV100434041; called by muse, mutect2, varscan2
- ZBTB33 | c.1432G>T p.V478L | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.06); catalogued as COSV100434043; called by muse, mutect2, varscan2
- ZC3H13 | c.3275G>T p.S1092I | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.085); catalogued as COSV54452671, COSV99667429; called by muse, mutect2, varscan2
- ZFHX3 | c.1339G>T p.G447C | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV99195192; called by muse, mutect2
- ZFHX4 | c.4197T>G p.C1399W | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99255784; called by muse, mutect2, varscan2
- ZFHX4 | c.8910A>T p.K2970N | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV50763361; called by muse, mutect2, varscan2
- ZIC1 | c.791C>A p.P264Q | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99291494; called by mutect2, varscan2
- ZIC3 | c.1138C>A p.H380N | Missense Mutation (SNP) | VAF 40/223 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV54975684, COSV99798295; called by muse, mutect2, varscan2
- ZMYM3 | c.578C>A p.P193H | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.438); catalogued as COSV58741024; called by muse, mutect2, varscan2
- ZNF208 | c.1925G>T p.C642F | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101236790; called by muse, varscan2
- ZNF25 | c.1288G>T p.E430* | Nonsense Mutation (SNP) | VAF 10/94 reads (11%) | catalogued as COSV100224503; called by muse, mutect2
- ZNF274 | c.1696C>G p.Q566E (on ENST00000610905; = p.Q461E on NM_016324.3) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as COSV100464683; called by mutect2, varscan2
- ZNF549 | c.596A>T p.Q199L (on ENST00000376233 / NM_001199295.2; = p.Q186L on NM_153263.2) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.57); catalogued as COSV99558358; called by muse, mutect2, varscan2
- ZNF585B | c.15G>T p.W5C | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.085); catalogued as COSV101087026; called by muse, mutect2, varscan2
- ZNF648 | c.376C>A p.L126I | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.178); catalogued as rs1272215026, COSV100374415; called by muse, mutect2, varscan2
- ZNF831 | c.4904C>G p.P1635R | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV100925756, COSV100926041; called by muse, mutect2
- ZP4 | c.663T>G p.S221R | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as COSV100850554; called by muse, mutect2, varscan2
- ABCC9 | c.1874_1883del p.S625Lfs*15 | Frame Shift Del (DEL) | VAF 30/95 reads (32%) | called by mutect2, pindel, varscan2
- AMY1C | c.897G>C p.W299C | Missense Mutation (SNP) | VAF 14/330 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARHGAP19 | c.188G>T p.S63I | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.71); called by muse, mutect2
- ASAH2 | c.511G>T p.V171F | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- FAM153B | c.1124G>T p.W375L (on ENST00000253490; = p.W298L on NM_001265615.1) | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.702); called by mutect2, varscan2
- FBF1 | c.2659dup p.W887Lfs*12 (on ENST00000586717; = p.W901Lfs*12 on NM_001319193.1) | Frame Shift Ins (INS) | VAF 7/24 reads (29%) | called by mutect2, pindel, varscan2
- FUT8 | c.1374_1375del p.Q459Gfs*18 (on ENST00000360689 / NM_001371534.1; = p.Q296Gfs*18 on NM_004480.4) | Frame Shift Del (DEL) | VAF 10/100 reads (10%) | called by pindel, varscan2
- GCC1 | c.2266_2268del p.E756del | In Frame Del (DEL) | VAF 17/79 reads (22%) | called by pindel, varscan2*
- GDF2 | c.978C>A p.H326Q | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- IGHV1-24 | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 11/182 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.705); called by muse, mutect2
- IGHV2-26 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); called by muse, varscan2
- IGHV2-26 | c.276G>T p.K92N | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, varscan2
- MRC1 | c.2821G>T p.V941F | Missense Mutation (SNP) | VAF 23/287 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.11); called by muse, mutect2
- SLC34A1 | c.1525del p.A509Pfs*34 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | called by mutect2, pindel, varscan2
- TSKU | c.788del p.G263Afs*16 | Frame Shift Del (DEL) | VAF 10/80 reads (13%) | called by mutect2, varscan2
- WDR55 | c.43G>T p.D15Y | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- ABCB1 | c.3337C>T p.L1113= | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as COSV99712083, COSV99712164; called by muse, mutect2, varscan2
- ABCC1 | c.2340G>T p.R780= | Silent (SNP) | VAF 23/81 reads (28%) | catalogued as rs1244749123, COSV100578487; called by muse, mutect2, varscan2
- ADAM18 | c.1620T>A p.P540= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs753163568, COSV55856884, COSV99694853; called by muse, mutect2
- ADAMTS5 | c.2511A>T p.T837= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as COSV99537005; called by muse, mutect2, varscan2
- ADGRA2 | c.1545C>A p.I515= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV100177513, COSV59442490; called by muse, mutect2, varscan2
- ADTRP | c.157T>C p.L53= | Silent (SNP) | VAF 11/82 reads (13%) | catalogued as COSV99995021; called by muse, mutect2, varscan2
- AFF2 | c.1380T>A p.P460= | Silent (SNP) | VAF 23/131 reads (18%) | catalogued as COSV99661811; called by muse, mutect2, varscan2
- AHNAK2 | c.13986T>A p.T4662= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs1454719707, COSV100315491; called by muse, mutect2, varscan2
- ALDH1A2 | c.330A>T p.A110= | Silent (SNP) | VAF 25/245 reads (10%) | catalogued as COSV99990333; called by muse, mutect2, varscan2
- ARNTL | c.318C>T p.S106= | Silent (SNP) | VAF 35/131 reads (27%) | catalogued as COSV100724547; called by muse, mutect2, varscan2
- ARNTL | c.498A>T p.R166= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as COSV100724549; called by muse, mutect2, varscan2
- ASPG | c.339C>A p.I113= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV101496340; called by muse, mutect2, varscan2
- ATP7A | c.297A>G p.P99= | Silent (SNP) | VAF 76/326 reads (23%) | catalogued as COSV100430221; called by muse, varscan2
- BTK | c.1776C>A p.S592= | Silent (SNP) | VAF 18/150 reads (12%) | catalogued as COSV100437281; called by muse, mutect2, varscan2
- C11orf1 | c.213C>G p.G71= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV99499451; called by muse, mutect2, varscan2
- CABP2 | c.537G>T p.A179= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs773753281, COSV99590714; called by muse, mutect2, varscan2
- CABP4 | c.477G>T p.R159= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV100351426; called by muse, mutect2, varscan2
- CCL26 | c.96C>A p.T32= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as COSV50013657; called by muse, mutect2
- CCT8L2 | c.84G>A p.E28= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV100742552; called by muse, mutect2, varscan2
- CDH7 | c.150G>A p.V50= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs754009152, COSV100541259, COSV100541396; called by muse, mutect2, varscan2
- CEBPZ | c.150C>T p.G50= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV99135401; called by muse, mutect2
- CENPE | c.5559G>A p.K1853= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV99476953, COSV99478750; called by muse, mutect2, varscan2
- CNKSR2 | c.1860G>T p.L620= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV99667289; called by muse, mutect2, varscan2
- CNTNAP4 | c.1404G>T p.A468= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV56690108, COSV56696558; called by mutect2, varscan2
- COL1A2 | c.879C>A p.P293= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV99798520; called by muse, mutect2, varscan2
- CPN2 | c.69C>A p.P23= | Silent (SNP) | VAF 3/40 reads (8%) | catalogued as COSV100102855; called by muse, mutect2
- DCAF16 | c.303C>T p.S101= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as COSV101200391; called by muse, mutect2, varscan2
- DDX54 | c.825G>A p.V275= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV58375103; called by muse, mutect2, varscan2
- DENND2B | c.1758G>T p.L586= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as COSV100567116; called by muse, mutect2, varscan2
- DHX35 | c.651G>T p.R217= | Silent (SNP) | VAF 11/83 reads (13%) | catalogued as COSV99326390; called by muse, mutect2
- DLX5 | c.801C>A p.I267= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV99756212; called by muse, mutect2, varscan2
- DST | c.22335G>T p.T7445= (on ENST00000361203 / NM_001374722.1; = p.T5155= on NM_015548.5) | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV99750886; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1950G>T p.L650= (on ENST00000361735 / NM_015935.5; = p.L564= on NM_014955.3) | Silent (SNP) | VAF 19/88 reads (22%) | catalogued as COSV100675761; called by muse, mutect2, varscan2
- ENPP1 | c.1830C>A p.P610= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV100719374; called by muse, mutect2
- F8 | c.2550G>T p.L850= | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as rs782777398, COSV100811494, COSV64275595; called by muse, mutect2, varscan2
- FAM83B | c.225A>T p.T75= | Silent (SNP) | VAF 26/102 reads (25%) | catalogued as COSV100174006; called by muse, mutect2, varscan2
- FBXO15 | c.1434G>A p.E478= | Silent (SNP) | VAF 27/104 reads (26%) | catalogued as COSV99503019; called by muse, mutect2, varscan2
- FCGR2C | c.639C>A p.V213= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV100912482; called by muse, mutect2
- GABBR2 | c.1461C>T p.A487= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV99409141; called by muse, mutect2, varscan2
- GABRR1 | c.978C>A p.T326= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs1293965622, COSV101033734; called by muse, mutect2, varscan2
- GIGYF2 | c.2073C>T p.I691= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV101003855; called by mutect2, varscan2
- GJB2 | c.81C>T p.V27= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV101241467; called by muse, mutect2, varscan2
- GJB6 | c.225G>A p.R75= | Silent (SNP) | VAF 3/28 reads (11%) | catalogued as rs1223817885; called by muse, mutect2
- GLI1 | c.714T>A p.R238= | Silent (SNP) | VAF 10/134 reads (7%) | catalogued as COSV99953658; called by muse, mutect2
- GPR141 | c.567C>A p.V189= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV100550214, COSV100550345; called by muse, mutect2, varscan2
- GPR50 | c.759C>A p.I253= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as COSV99505614; called by muse, mutect2, varscan2
- GRM2 | c.2592G>A p.V864= | Silent (SNP) | VAF 13/193 reads (7%) | catalogued as rs758084668, COSV99622413; called by muse, mutect2
- HECW1 | c.3177C>T p.P1059= | Silent (SNP) | VAF 28/97 reads (29%) | catalogued as COSV101222793; called by muse, mutect2, varscan2
- HPCA | c.352C>A p.R118= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV100992158, COSV65102808; called by muse, mutect2, varscan2
- HPS5 | c.228A>T p.A76= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV100834337; called by muse, mutect2, varscan2
- HS3ST2 | c.603C>A p.I201= | Silent (SNP) | VAF 25/92 reads (27%) | catalogued as COSV54466235, COSV99757734; called by muse, mutect2, varscan2
- HSPG2 | c.1443C>T p.A481= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs369519412; called by muse, mutect2, varscan2
- IGHMBP2 | c.609G>T p.A203= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs761677597, COSV54821710, COSV99661770; called by muse, mutect2, varscan2
- IL1RAPL2 | c.2010T>A p.S670= | Silent (SNP) | VAF 24/123 reads (20%) | catalogued as COSV100780713; called by muse, mutect2, varscan2
- IL1RL2 | c.1395G>T p.L465= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV99960204; called by muse, varscan2
- IRX5 | c.336G>T p.G112= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV100315617; called by muse, mutect2, varscan2
- ITGAL | c.174G>A p.V58= | Silent (SNP) | VAF 27/87 reads (31%) | catalogued as COSV100776058; called by muse, mutect2, varscan2
- KCNH4 | c.639G>A p.G213= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as COSV99236720; called by muse, mutect2, varscan2
- KLHL4 | c.1065T>C p.H355= | Silent (SNP) | VAF 19/105 reads (18%) | catalogued as COSV100909086; called by muse, mutect2
- KRT86 | c.822C>A p.I274= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as COSV99524840; called by muse, mutect2, varscan2
- LRFN4 | c.33C>A p.A11= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV100540666; called by muse, mutect2
- LRP2 | c.2631C>T p.I877= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs139833815; called by muse, mutect2, varscan2
- LRRC8C | c.957G>T p.L319= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as COSV100968001; called by muse, mutect2
- LY6D | c.105T>A p.S35= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV100009227; called by muse, mutect2, varscan2
- MPPED2 | c.714G>T p.T238= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV63897342, COSV63900722; called by muse, mutect2, varscan2
- MR1 | c.12G>T p.L4= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV51580676, COSV99294770; called by muse, mutect2, varscan2
- MRC1 | c.3435G>A p.Q1145= | Silent (SNP) | VAF 96/429 reads (22%) | called by muse, varscan2
- MUC17 | c.9018C>A p.T3006= | Silent (SNP) | VAF 52/330 reads (16%) | catalogued as COSV100071551; called by muse, varscan2
- MYT1 | c.3231G>T p.P1077= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as COSV60510079; called by muse, mutect2, varscan2
- NAV2 | c.6168G>T p.G2056= (on ENST00000396087 / NM_001244963.2; = p.G1997= on NM_145117.5) | Silent (SNP) | VAF 25/105 reads (24%) | catalogued as COSV100216062; called by muse, mutect2, varscan2
- NKAIN3 | c.135A>C p.I45= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as COSV100131329, COSV60683728; called by muse, mutect2, varscan2
- NLRP4 | c.1404C>T p.S468= | Silent (SNP) | VAF 37/106 reads (35%) | catalogued as rs368640921; called by muse, mutect2, varscan2
- NOX5 | c.1443C>A p.I481= | Silent (SNP) | VAF 18/157 reads (11%) | catalogued as COSV52988729; called by muse, mutect2, varscan2
- NRAP | c.4974C>T p.D1658= (on ENST00000359988 / NM_001322945.2; = p.D1623= on NM_006175.4) | Silent (SNP) | VAF 5/64 reads (8%) | catalogued as rs1017080064, COSV100667791; called by muse, mutect2
- NRG1 | c.813G>T p.R271= (on ENST00000405005 / NM_013964.5; = p.R276= on NM_013956.5) | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as rs766237453, COSV99827568; called by muse, mutect2, varscan2
- ODF3L2 | c.336G>T p.R112= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as COSV100205241; called by muse, mutect2, varscan2
- OR1L4 | c.90C>T p.A30= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as COSV99413771; called by muse, mutect2
- OR2T4 | c.33T>A p.T11= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV100822392; called by muse, mutect2, varscan2
- OR52A1 | c.897C>A p.T299= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as COSV100200407; called by muse, mutect2, varscan2
- OR5T3 | c.147T>C p.F49= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as COSV100282668; called by muse, mutect2, varscan2
- OR6S1 | c.198T>A p.G66= | Silent (SNP) | VAF 4/63 reads (6%) | catalogued as COSV100289260; called by muse, mutect2
- OR8B8 | c.756T>C p.F252= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as COSV100044806; called by muse, mutect2, varscan2
- OR8J1 | c.339C>A p.I113= | Silent (SNP) | VAF 16/101 reads (16%) | catalogued as COSV100274857; called by muse, mutect2, varscan2
- P2RY8 | c.963C>A p.R321= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as COSV101183932; called by muse, mutect2, varscan2
- PCDHGA10 | c.192G>T p.A64= | Silent (SNP) | VAF 24/87 reads (28%) | catalogued as COSV99530326; called by muse, mutect2, varscan2
- PDE2A | c.1833C>G p.P611= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs201331559, COSV100557604; called by muse, mutect2, varscan2
- PDYN | c.99C>A p.T33= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV99452655; called by muse, mutect2, varscan2
- PMFBP1 | c.87G>T p.L29= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV99400131; called by muse, mutect2, varscan2
- POTEF | c.2322C>A p.G774= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV100664553; called by muse, mutect2, varscan2
- PRAMEF18 | c.246G>T p.V82= | Silent (SNP) | VAF 27/279 reads (10%) | called by muse, mutect2
- PRDM11 | c.426G>T p.R142= (on ENST00000530656 / NM_001359633.1; = p.R108= on NM_001256695.1) | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs1239706003, COSV55444050, COSV99770325; called by muse, mutect2
- PRRX1 | c.594G>T p.P198= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV53414441, COSV99509215; called by muse, mutect2, varscan2
- PRSS58 | c.135G>T p.L45= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as rs1317798392, COSV101616084, COSV73488534; called by muse, mutect2, varscan2
- PRTG | c.1710G>T p.P570= | Silent (SNP) | VAF 8/68 reads (12%) | called by mutect2, varscan2
- PSG1 | c.9C>A p.T3= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as COSV54944119; called by muse, mutect2, varscan2
- PSG9 | c.1200C>A p.A400= | Silent (SNP) | VAF 26/137 reads (19%) | catalogued as COSV99392037; called by muse, mutect2, varscan2
- PXDNL | c.2493G>T p.P831= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV100681216, COSV62481028; called by muse, mutect2, varscan2
- RAB6B | c.471G>T p.A157= | Silent (SNP) | VAF 13/125 reads (10%) | catalogued as COSV53314803, COSV99557749; called by muse, mutect2, varscan2
- RAD51D | c.885G>T p.L295= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV100238957; called by muse, mutect2, varscan2
- RGS18 | c.210C>A p.A70= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs745502461, COSV100817648; called by muse, mutect2, varscan2
- RIMS2 | c.1191A>T p.I397= (on ENST00000666250 / NM_001348490.2; = p.I205= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as COSV99158703; called by muse, mutect2
- RPS6KA1 | c.1068G>T p.T356= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV100837889; called by muse, mutect2, varscan2
- RTTN | c.168G>T p.P56= | Silent (SNP) | VAF 37/122 reads (30%) | catalogued as COSV99730973; called by muse, mutect2, varscan2
- RUNX2 | c.435C>A p.L145= | Silent (SNP) | VAF 31/110 reads (28%) | catalogued as COSV100767108; called by muse, mutect2, varscan2
- RYR2 | c.12762C>A p.T4254= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as COSV63707833; called by muse, mutect2
- SDF2 | c.141C>T p.R47= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV99897822; called by muse, mutect2, varscan2
- SHANK1 | c.1986G>A p.K662= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV99520153; called by muse, mutect2, varscan2
- SIX1 | c.453G>T p.P151= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as rs1225739224, COSV99903225; called by muse, mutect2, varscan2
- SIX3 | c.309C>A p.G103= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV99578042; called by muse, mutect2, varscan2
- SLC22A12 | c.682C>A p.R228= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV100327348; called by muse, mutect2, varscan2
- SLC38A11 | c.864C>A p.V288= (on ENST00000409149 / NM_001351539.1; = p.V266= on NM_173512.2) | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as COSV100366713; called by mutect2, varscan2
- SLITRK1 | c.474G>T p.V158= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as rs1475032414, COSV65674738; called by muse, mutect2, varscan2
- SORCS1 | c.3108C>A p.V1036= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV99543127; called by muse, mutect2
- SPDYE3 | c.1245G>A p.L415= | Silent (SNP) | VAF 10/298 reads (3%) | catalogued as COSV100193334; called by muse, mutect2
- SPECC1 | c.453C>T p.S151= | Silent (SNP) | VAF 15/91 reads (16%) | catalogued as COSV99821217; called by muse, mutect2, varscan2
- SPRR2B | c.87C>A p.P29= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as COSV100482230; called by muse, mutect2, varscan2
- SQSTM1 | c.9G>T p.S3= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV100657619; called by muse, varscan2
- SUCNR1 | c.750C>A p.V250= | Silent (SNP) | VAF 14/123 reads (11%) | catalogued as rs200218473, COSV100751679; called by muse, mutect2, varscan2
- TBPL2 | c.1023C>A p.I341= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV55973059, COSV99905284; called by muse, mutect2, varscan2
- TENM1 | c.4197C>T p.I1399= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as rs780736152, COSV64432445; called by muse, mutect2, varscan2
- TENM3 | c.2550C>T p.T850= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs1172852649, COSV101304871; called by muse, mutect2, varscan2
- TMCO3 | c.1785G>T p.A595= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV100952265; called by muse, mutect2, varscan2
- TMEM132E | c.837G>T p.V279= (on ENST00000321639; = p.V369= on NM_001304438.2) | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100395921; called by muse, mutect2
- TMEM176B | c.168C>T p.S56= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV99133532; called by muse, mutect2
- TMEM202 | c.408C>A p.L136= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV100499097; called by muse, mutect2, varscan2
- TMEM215 | c.465G>A p.Q155= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as COSV100713135; called by muse, mutect2
- TTN | c.1380C>A p.I460= | Silent (SNP) | VAF 12/115 reads (10%) | catalogued as rs1035609321, COSV100593463; called by muse, mutect2, varscan2
- XIRP1 | c.3219G>A p.L1073= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs1325605297, COSV100453352; called by muse, mutect2, varscan2
- XKR3 | c.903G>T p.V301= | Silent (SNP) | VAF 13/61 reads (21%) | called by muse, mutect2, varscan2
- ZFHX3 | c.1338G>T p.V446= | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as COSV99195194; called by muse, mutect2
- ZFX | c.822T>C p.S274= | Silent (SNP) | VAF 23/101 reads (23%) | catalogued as COSV100457290; called by muse, mutect2, varscan2
- ZNF423 | c.1755C>T p.I585= (on ENST00000563137 / NM_001379286.1; = p.I577= on NM_015069.4) | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs1327728172, COSV99279697; called by muse, mutect2, varscan2
- ZNF425 | c.1803G>T p.L601= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as rs1235941696, COSV100955381; called by muse, mutect2, varscan2
- ZSCAN5B | c.561C>T p.P187= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV100748337; called by muse, mutect2, varscan2
- ANXA13 | c.15+1548C>A | Intron (SNP) | VAF 17/91 reads (19%) | catalogued as COSV99146035; called by muse, mutect2, varscan2
- ARHGEF25 | chr12:57620450 C>T | 3'Flank (SNP) | VAF 401/581 reads (69%) | catalogued as COSV99677491; called by muse, mutect2, varscan2
- DENND10P1 | n.325T>A | RNA (SNP) | VAF 20/100 reads (20%) | called by muse, mutect2, varscan2
- IGLV8OR8-1 | n.185G>C | RNA (SNP) | VAF 15/72 reads (21%) | called by muse, mutect2, varscan2
- MT1A | c.*2G>A | 3'UTR (SNP) | VAF 9/62 reads (15%) | catalogued as COSV99319151; called by muse, mutect2, varscan2
- NBPF11 | c.-548-2842G>T | Intron (SNP) | VAF 5/19 reads (26%) | called by muse, mutect2, varscan2
- ODF2L | chr1:86348809 C>T | 3'Flank (SNP) | VAF 3/32 reads (9%) | catalogued as COSV99643800; called by muse, mutect2
- PPP2R3A | c.1996-3751G>C | Intron (SNP) | VAF 7/61 reads (11%) | catalogued as COSV99386412; called by muse, mutect2, varscan2
- SNORD116-12 | n.32T>A | RNA (SNP) | VAF 20/102 reads (20%) | called by muse, mutect2, varscan2
- SORBS1 | c.3640-759G>T | Intron (SNP) | VAF 15/65 reads (23%) | catalogued as rs771443515, COSV99527383; called by muse, mutect2, varscan2
- SSPOP | n.4270A>T | RNA (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100022127; called by muse, mutect2, varscan2
- SSPOP | n.14535C>T | RNA (SNP) | VAF 4/19 reads (21%) | catalogued as COSV100946970; called by muse, mutect2
- SYTL2 | c.1459+3179A>T | Intron (SNP) | VAF 10/65 reads (15%) | catalogued as rs754776868, COSV100313620; called by muse, mutect2, varscan2
- TMEM132E | chr17:34578992 G>T | 5'Flank (SNP) | VAF 11/76 reads (14%) | catalogued as rs766034869; called by muse, mutect2, varscan2
- TTN | c.10361-4656C>T | Intron (SNP) | VAF 4/31 reads (13%) | catalogued as COSV100593461; called by muse, mutect2, varscan2
- UNC5D | c.104-4836G>C | Intron (SNP) | VAF 5/32 reads (16%) | catalogued as COSV99771965; called by muse, mutect2, varscan2
- XCL2 | c.-2C>A | 5'UTR (SNP) | VAF 9/69 reads (13%) | catalogued as COSV100892240; called by muse, mutect2, varscan2
